Somatic mutation profile of tumor specimen ALCH-B2D1-TTP1-A (aliquot ALCH-B2D1-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2D1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 54.2 years (19,814 days).
Specimen ALCH-B2D1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcccb34b-47e7-4dff-a18f-80130fa7a8d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2D1-NB1-A (Blood Derived Normal), aliquot ALCH-B2D1-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bd56338-ca30-424b-bff0-0aef29c91a5c

The open-access MAF lists 444 somatic variants for this specimen: 297 protein-altering or splice-affecting, 87 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 263, Silent 87, Intron 23, Nonsense Mutation 18, Splice Site 10, RNA 8, 5'UTR 8, 3'UTR 8, 5'Flank 7, 3'Flank 6, Splice Region 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2446A>G p.T816A | Missense Mutation (SNP) | VAF 66/587 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV99072342; called by muse, mutect2, varscan2
- ABCB10 | c.1674C>G p.I558M | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60622200, COSV60623250; called by muse, mutect2
- ABCG5 | c.1885T>A p.S629T | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs999477425; called by muse, mutect2
- AL441992.2 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.709); catalogued as COSV100223795; called by muse, mutect2
- ANKRD35 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs145719512; called by muse, mutect2
- AR | c.1196G>T p.W399L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); catalogued as CM1515326; called by muse, mutect2, varscan2
- ARMH4 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV50766306; called by muse, mutect2
- BRINP3 | c.1811C>A p.P604H | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV66523873; called by muse, mutect2
- CASP10 | c.420C>A p.D140E | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs1053872104, COSV53780482; called by muse, mutect2
- CCZ1B | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.332); catalogued as rs565675264; called by muse, mutect2
- CDH10 | c.891C>A p.D297E | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52569471, COSV52598934; called by muse, mutect2
- CDK6 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as COSV56008604; called by muse, mutect2
- CFHR1 | c.401G>T p.W134L | Missense Mutation (SNP) | VAF 28/740 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57627849; called by muse, mutect2
- CHST1 | c.728G>C p.R243P | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323150; called by muse, mutect2
- COL9A1 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 15/490 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.4); catalogued as COSV57884310; called by muse, mutect2
- CUX2 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1247021979, COSV99920465; called by muse, mutect2, varscan2
- DCDC1 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100664438; called by muse, mutect2
- DISC1 | c.998G>T p.W333L | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV99698442; called by muse, mutect2
- DLEC1 | c.2056G>T p.G686W | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164548489; called by muse, mutect2
- EGLN3 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51656541; called by muse, mutect2
- ERCC3 | c.2218G>T p.A740S | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs1171070703, COSV53427508; called by muse, mutect2
- FGD6 | c.2261A>G p.Y754C | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1231459663; called by muse, mutect2
- FLG | c.6811G>C p.A2271P | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs769135798, COSV100912473; called by muse, mutect2
- FLG | c.4898C>A p.P1633H | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV100912499; called by muse, mutect2
- GAD2 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52153786; called by muse, mutect2
- GALNT17 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356756, COSV61196496; called by muse, mutect2
- GATA4 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV58733117; called by muse, mutect2
- GRIK4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs1218190526; called by muse, mutect2
- GRM7 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.995); catalogued as COSV100736198; called by muse, mutect2
- HSPA6 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59060840; called by muse, mutect2
- IRS4 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100929681; called by muse, mutect2
- ITIH6 | c.686del p.P229Rfs*62 | Frame Shift Del (DEL) | VAF 15/117 reads (13%) | catalogued as COSV54487645, COSV99513755; called by mutect2, pindel, varscan2
- KEAP1 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV50262982, COSV50673533; called by muse, mutect2
- KIF2B | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV52130905; called by muse, mutect2
- KMT2D | c.15311G>A p.C5104Y | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56437823; called by muse, mutect2
- LCT | c.1933C>A p.L645M | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.754); catalogued as COSV99929026; called by muse, mutect2
- LENG8 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV100457733; called by muse, mutect2
- LILRA4 | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs200162955, COSV52490716; called by muse, mutect2
- LRBA | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV63952775; called by muse, mutect2
- LRFN5 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53273822; called by muse, mutect2
- LTBP2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.049); catalogued as rs940757109; called by muse, mutect2
- MACROD2 | c.1241C>T p.P414L (on ENST00000642719; = p.P386L on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1378408899; called by muse, mutect2
- MSANTD2 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs868832012; called by muse, mutect2
- MUC16 | c.25639G>A p.V8547M | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV101200306; called by muse, mutect2
- NLRP3 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60225120; called by muse, mutect2
- OR2C3 | c.565G>C p.A189P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100825708; called by muse, mutect2
- OR2F1 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101231327; called by muse, mutect2, varscan2
- OXR1 | c.1343C>G p.S448* (on ENST00000442977 / NM_001198532.1; = p.S447* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 7/174 reads (4%) | catalogued as COSV100367635; called by muse, mutect2
- PAX8 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV54509527; called by muse, mutect2
- PCDHA11 | c.1377C>A p.Y459* | Nonsense Mutation (SNP) | VAF 19/205 reads (9%) | catalogued as COSV56538778; called by muse, mutect2
- PDE6A | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1399015433; called by muse, mutect2
- PIEZO2 | c.7508C>T p.S2503L | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53294243; called by muse, mutect2
- PRELP | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1410468623; called by muse, mutect2
- PRKCH | c.1399C>T p.L467F | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998164413; called by muse, mutect2
- RHOBTB3 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV101183212; called by muse, mutect2
- RSPH6A | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as rs371876198; called by muse, mutect2
- RYR1 | c.6274+1G>T p.X2092_splice | Splice Site (SNP) | VAF 5/97 reads (5%) | catalogued as COSV62098396; called by muse, mutect2
- SAP25 | c.58G>T p.V20L (on ENST00000538735; = p.V118L on NM_001168682.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1316588795; called by muse, mutect2, varscan2
- SCN10A | c.5327G>A p.R1776K | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as COSV101479520; called by muse, mutect2
- SCN4A | c.2989+1G>T p.X997_splice | Splice Site (SNP) | VAF 10/67 reads (15%) | catalogued as rs1251695746, COSV71127181; called by muse, mutect2
- SEC16A | c.2914G>T p.G972C | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV51530518, COSV99259169; called by muse, mutect2
- SLITRK4 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62026086; called by muse, mutect2
- SP4 | c.1525C>G p.Q509E | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs1412727475; called by muse, mutect2
- SPANXD | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs782256697; called by muse, mutect2
- SSX3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV53644495; called by muse, mutect2
- ST8SIA6 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV66467707, COSV66471803; called by muse, mutect2
- TAS2R60 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.605); catalogued as rs1177662501; called by muse, mutect2
- TBL1XR1 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs935282343, COSV100763612; ClinVar: uncertain significance; called by muse, mutect2
- TERT | c.1573+6G>T | Splice Region (SNP) | VAF 10/96 reads (10%) | catalogued as rs1561213199; called by muse, mutect2
- TRDMT1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58320711; called by muse, mutect2
- TRIM56 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV60161867; called by muse, mutect2
- TTC9C | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 18/357 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV53665072, COSV99584673; called by muse, mutect2
- WDR91 | c.1590C>G p.I530M | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs968247433, COSV60369245; called by muse, mutect2
- WNT2 | c.187C>A p.R63S | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.176); catalogued as COSV55411972; called by muse, mutect2
- WSCD2 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99775381; called by muse, mutect2
- WSCD2 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99775365; called by muse, mutect2
- ZNF516 | c.3122C>A p.S1041Y | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs937182882; called by muse, mutect2
- ZNF726 | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 21/359 reads (6%) | catalogued as COSV58044812; called by muse, mutect2
- ACKR2 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); called by muse, mutect2
- ACTN3 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS9 | c.2362G>T p.G788W | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY8 | c.3577G>T p.A1193S | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); called by muse, mutect2
- ADGRE2 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG4 | c.4924C>A p.P1642T | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- AGBL5 | c.1766T>A p.L589Q | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AHNAK2 | c.2740G>T p.V914L | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.208); called by muse, mutect2
- AKAP12 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); called by muse, mutect2
- ALOXE3 | c.1958G>T p.R653M | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- AP5M1 | c.762G>C p.L254F | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARNT | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 32/363 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARRDC3 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 14/397 reads (4%) | called by muse, mutect2
- ASAP1 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 13/354 reads (4%) | called by muse, mutect2
- ATP4A | c.813C>A p.N271K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.744); called by muse, mutect2
- ATP8B4 | c.2845C>G p.L949V | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2
- ATRX | c.2180A>C p.Q727P | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- CACNA2D3 | c.2985C>A p.S995= | Splice Region (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- CADM2 | c.179C>A p.A60D (on ENST00000407528 / NM_001167674.2; = p.A62D on NM_153184.4) | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CADPS | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.055); called by muse, mutect2
- CALR3 | c.817G>T p.D273Y | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CAPNS1 | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2
- CASR | c.1603T>A p.F535I (on ENST00000490131; = p.F612I on NM_000388.4) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2
- CBR4 | c.711G>T p.L237F | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2
- CCDC116 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.052); called by muse, mutect2
- CCDC141 | c.4533G>T p.W1511C | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD40 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 10/291 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CD83 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.32); called by muse, mutect2
- CDC6 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 12/358 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH17 | c.1465T>A p.Y489N | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP250 | c.2754+1G>T p.X918_splice | Splice Site (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- CEP63 | c.1638C>A p.H546Q | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- CFAP300 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2
- CHD1L | c.2270A>T p.K757M | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.227); called by muse, mutect2
- CNTNAP1 | c.2373C>A p.H791Q | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.199); called by muse, mutect2
- COL4A4 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- COL6A6 | c.3127C>A p.Q1043K | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPNE8 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 9/266 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.314); called by muse, mutect2
- CRB2 | c.2158C>A p.R720S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.066); called by muse, mutect2
- CROCC | c.5176G>C p.D1726H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- CXCL13 | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.569); called by muse, mutect2
- DAP3 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- DCAF8L2 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2
- DIAPH1 | c.3508G>T p.E1170* | Nonsense Mutation (SNP) | VAF 36/742 reads (5%) | called by muse, mutect2
- DLC1 | c.4048G>T p.E1350* (on ENST00000276297 / NM_001348081.2; = p.E913* on NM_006094.5) | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- DLGAP2 | c.1971C>A p.S657R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.405); called by muse, mutect2
- DLL3 | c.1351del p.L451Sfs*97 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | called by mutect2, varscan2
- DNAH7 | c.6960A>G p.I2320M | Missense Mutation (SNP) | VAF 10/345 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- DOK4 | c.69C>A p.I23= | Splice Region (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- DTNB | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- EIF4E2 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2
- ELFN1 | c.836C>A p.P279Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- EMX1 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- EOMES | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.469); called by muse, mutect2
- EP400 | c.9209A>T p.Q3070L | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- EPN1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.244); called by muse, mutect2
- FBF1 | c.2776G>A p.A926T (on ENST00000586717; = p.A941T on NM_001319193.1) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBLN1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- FCGR1A | c.307+1G>T p.X103_splice | Splice Site (SNP) | VAF 39/536 reads (7%) | called by muse, mutect2
- FER1L5 | c.1309G>T p.G437C (on ENST00000623019; = p.G442C on NM_001293083.2) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FFAR2 | c.305dup p.I103Hfs*52 | Frame Shift Ins (INS) | VAF 12/111 reads (11%) | called by mutect2, pindel
- FMO5 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.026); called by muse, mutect2
- FMR1NB | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- FOXF1 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXRED2 | c.1409A>T p.E470V | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- G2E3 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.34); called by muse, mutect2
- GAS2L3 | c.1563G>C p.M521I | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- GH2 | c.527C>A p.S176* | Nonsense Mutation (SNP) | VAF 19/473 reads (4%) | called by muse, mutect2
- GOLGA6L2 | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- GRHL1 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN2A | c.3551A>G p.Y1184C | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- GRM7 | c.828C>A p.D276E | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- HCRTR2 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 21/434 reads (5%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.067); called by muse, mutect2
- HDC | c.917G>T p.W306L | Missense Mutation (SNP) | VAF 16/437 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- HDGFL1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HEATR5B | c.1126G>T p.A376S | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.172); called by muse, mutect2
- HELZ2 | c.2971G>T p.V991L (on ENST00000467148 / NM_001037335.2; = p.V422L on NM_033405.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HIBCH | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- HMCN1 | c.5094A>T p.E1698D | Missense Mutation (SNP) | VAF 16/528 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- HOXC12 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HS3ST4 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- HSPA2 | c.1386C>A p.F462L | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- IGHD | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.041); called by muse, mutect2
- IGLV3-9 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 13/400 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- IL20RB | c.625G>T p.V209L | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL7R | c.1105T>A p.C369S | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2
- INSRR | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- IPO8 | c.911T>A p.V304E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IQCE | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.766); called by muse, mutect2
- IZUMO1R | c.224G>T p.S75I | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- IZUMO3 | c.46C>A p.H16N | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.01); called by muse, mutect2
- KCNT1 | c.2788G>T p.E930* (on ENST00000488444; = p.E949* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- KIF17 | c.2446G>T p.E816* | Nonsense Mutation (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- KIF1B | c.3260-2A>G p.X1087_splice (on ENST00000377086 / NM_001365952.1; = p.X1041_splice on NM_015074.3) | Splice Site (SNP) | VAF 11/268 reads (4%) | called by muse, mutect2
- KIF4B | c.2125G>C p.A709P | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- KIZ | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- KLHL42 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 15/263 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- KRTAP1-1 | c.446C>G p.A149G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- LAMA1 | c.5169-1G>C p.X1723_splice | Splice Site (SNP) | VAF 15/318 reads (5%) | called by muse, mutect2
- LDLRAD3 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.104); called by muse, mutect2
- LHCGR | c.1823T>C p.L608P | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LILRA2 | c.1418G>A p.S473N (on ENST00000391738 / NM_001130917.3; = p.S456N on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.465); called by muse, mutect2
- LILRA4 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 9/296 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- LRFN2 | c.784C>A p.L262M | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.14); called by muse, mutect2
- LSG1 | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- MAGI2 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- MAGI2 | c.717G>T p.R239S | Missense Mutation (SNP) | VAF 11/402 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- MAP3K19 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2
- MATK | c.1354C>A p.P452T (on ENST00000310132 / NM_139355.3; = p.P453T on NM_002378.4) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAX | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.24); called by muse, mutect2
- MON2 | c.2793G>T p.L931F | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MPHOSPH9 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- MRC1 | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.892); called by muse, mutect2
- MSMB | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2
- MTBP | c.2270A>T p.E757V | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- NAV1 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- NIPBL | c.1890G>T p.L630F | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.06); called by muse, mutect2
- NLRP3 | c.2150+1G>T p.X717_splice | Splice Site (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- NPIPB2 | c.1181G>T p.C394F (on ENST00000399147; = p.C254F on NM_001355514.1) | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2
- NPTXR | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2
- NRK | c.2510C>T p.S837L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2
- NSD1 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUP54 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 12/318 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2
- NUP54 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- NWD2 | c.2901C>A p.H967Q | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.047); called by muse, mutect2
- OR13A1 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2
- OR2M5 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- OR5D14 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- OR5H15 | c.553T>C p.S185P | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2
- OTUD3 | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- PAK5 | c.120C>A p.H40Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PBX1 | c.1215G>C p.W405C | Missense Mutation (SNP) | VAF 14/215 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2
- PCDH11Y | c.581C>G p.A194G (on ENST00000400457 / NM_032973.2; = p.A183G on NM_032971.3) | Missense Mutation (SNP) | VAF 24/377 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PCDHA8 | c.2194T>G p.C732G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB12 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.904); called by muse, mutect2
- PCDHB9 | c.2261G>T p.C754F | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2
- PCNT | c.3286C>G p.Q1096E | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- PFDN2 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- PITPNB | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.619); called by muse, mutect2
- PLA2G2A | c.397T>A p.S133T | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PLXNA1 | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLXNA4 | c.4940G>T p.S1647I | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PNMA3 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PPFIA4 | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- PRAMEF20 | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 13/430 reads (3%) | called by muse, mutect2
- PRKDC | c.9811G>T p.D3271Y | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PRR7 | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.116); called by muse, mutect2
- PRRC2C | c.3157G>A p.E1053K (on ENST00000367742; = p.E1051K on NM_015172.4) | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2
- PRRT4 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2
- PRRX1 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- PSG1 | c.314C>A p.A105E | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PSG8 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.626); called by muse, mutect2
- RFPL4A | c.617C>A p.P206H | Missense Mutation (SNP) | VAF 20/743 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- RHBDD2 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RMND5A | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2
- RTL1 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.939); called by muse, varscan2
- RTL9 | c.3763G>T p.D1255Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- RTN3 | c.2296G>T p.A766S (on ENST00000377819 / NM_001265589.2; = p.A747S on NM_201428.3) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- RTP1 | c.188G>T p.W63L | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RXFP3 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2
- RYR2 | c.2822A>T p.K941M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SACS | c.2832G>C p.L944F | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.849); called by muse, mutect2
- SAGE1 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SARAF | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2
- SCARB1 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- SCN3A | c.3797C>T p.T1266I | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2
- SDK1 | c.3824-2A>T p.X1275_splice | Splice Site (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- SELE | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- SELE | c.815G>T p.C272F | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SELENOM | c.201-3_201-2del p.X67_splice | Splice Site (DEL) | VAF 13/102 reads (13%) | called by mutect2, pindel, varscan2
- SLC3A1 | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- SLC5A1 | c.1891A>G p.K631E | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- SLC5A5 | c.1536G>T p.M512I | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2
- SLC6A7 | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.2); called by muse, mutect2
- SMG7 | c.2104T>A p.S702T | Missense Mutation (SNP) | VAF 17/435 reads (4%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- SNX12 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- SP3 | c.554A>T p.Q185L | Missense Mutation (SNP) | VAF 13/388 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.115); called by muse, mutect2
- SPHKAP | c.257T>A p.V86E | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ST3GAL3 | c.217G>A p.D73N (on ENST00000361392 / NM_174964.4; = p.D58N on NM_006279.5) | Missense Mutation (SNP) | VAF 28/555 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ST8SIA2 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 31/471 reads (7%) | PolyPhen benign (0.035); called by muse, mutect2
- STC2 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- SVIL | c.5572T>A p.C1858S (on ENST00000355867 / NM_021738.3; = p.C1432S on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- SYT14 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- TBRG4 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- TEP1 | c.2526-1G>T p.X842_splice | Splice Site (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- TFDP3 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- TGIF2LX | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.36); called by muse, mutect2
- TMEM132B | c.1753C>A p.Q585K | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2
- TMEM47 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.048); called by muse, mutect2
- TMEM89 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- TRAV16 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- TRDV3 | c.227C>G p.A76G | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); called by muse, mutect2
- TSKS | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.015); called by mutect2, varscan2
- TTC14 | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC28 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- UBN2 | c.1871A>T p.Y624F | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); called by muse, mutect2
- UHRF1BP1L | c.4033G>T p.D1345Y | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- USP26 | c.1165C>G p.H389D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.698); called by muse, mutect2
- VPS50 | c.542A>T p.Q181L | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VSTM2A | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VSTM2A | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 85/399 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- VWA3B | c.2770C>A p.Q924K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2
- WDPCP | c.136T>G p.L46V | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2
- WDR7 | c.1583G>C p.R528T | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- WIZ | c.4322G>T p.G1441V (on ENST00000673675 / NM_001371589.1; = p.G346V on NM_021241.3) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.299); called by muse, mutect2
- XXYLT1 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2
- ZFP28 | c.2132G>T p.G711V | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2
- ZIC1 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2
- ZNF124 | c.736C>G p.L246V (on ENST00000543802 / NM_001297568.1; = p.L184V on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- ZNF260 | c.583A>G p.S195G | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- ZNF285 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.103); called by muse, mutect2
- ZNF345 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF425 | c.926G>C p.R309P | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ZNF546 | c.2508G>T p.M836I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF582 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- ZNF622 | c.1218G>T p.L406F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); called by muse, mutect2
- ZNF780B | c.1828G>T p.E610* | Nonsense Mutation (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- ZNF782 | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF804B | c.201C>G p.H67Q | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCC12 | c.1632C>A p.A544= | Silent (SNP) | VAF 10/284 reads (4%) | called by muse, mutect2
- ABHD6 | c.327G>A p.E109= | Silent (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- ADAMTS16 | c.2898G>T p.P966= | Silent (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- AL121899.2 | c.588C>T p.N196= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV67351184; called by muse, mutect2
- ALPK3 | c.3600G>T p.L1200= | Silent (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- AMOTL2 | c.1686G>T p.L562= | Silent (SNP) | VAF 14/227 reads (6%) | called by muse, mutect2
- AMPH | c.1371G>T p.R457= | Silent (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- ARAP3 | c.1782C>T p.I594= | Silent (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- ASTN2 | c.2613C>A p.I871= (on ENST00000313400 / NM_001365069.1; = p.I820= on NM_014010.5) | Silent (SNP) | VAF 12/159 reads (8%) | called by muse, mutect2
- ATXN7 | c.87G>T p.R29= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, varscan2
- B2M | c.30C>G p.L10= | Silent (SNP) | VAF 13/449 reads (3%) | catalogued as COSV62563463; called by muse, mutect2
- BNC2 | c.2391G>C p.G797= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- BRD8 | c.3030A>G p.E1010= | Silent (SNP) | VAF 13/297 reads (4%) | called by muse, mutect2
- C2orf16 | c.351C>A p.I117= | Silent (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- C8A | c.24C>A p.I8= | Silent (SNP) | VAF 20/696 reads (3%) | catalogued as COSV63483232, COSV63483347; called by muse, mutect2
- CACNA1A | c.7272C>A p.A2424= | Silent (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- CDH10 | c.1845C>A p.I615= | Silent (SNP) | VAF 16/253 reads (6%) | catalogued as COSV52574073; called by muse, mutect2
- CDHR2 | c.1968C>T p.A656= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- CEACAM3 | c.669C>A p.P223= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- CRX | c.750C>A p.P250= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- CTSK | c.927C>A p.L309= | Silent (SNP) | VAF 18/524 reads (3%) | called by muse, mutect2
- DSCAML1 | c.1350C>A p.R450= (on ENST00000321322; = p.R390= on NM_020693.4) | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- DYSF | c.756G>C p.T252= | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as COSV50299706; called by muse, mutect2
- EIF2B4 | c.999C>A p.I333= (on ENST00000347454 / NM_001034116.2; = p.I332= on NM_015636.3) | Silent (SNP) | VAF 15/352 reads (4%) | catalogued as COSV52007309; called by muse, mutect2
- F13A1 | c.1980C>A p.T660= | Silent (SNP) | VAF 19/502 reads (4%) | called by muse, mutect2
- FAM170A | c.621C>A p.P207= | Silent (SNP) | VAF 15/145 reads (10%) | called by muse, mutect2, varscan2
- FAM47C | c.2391C>T p.S797= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- FAM83B | c.1474C>T p.L492= | Silent (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- GABRA3 | c.1197G>T p.V399= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as COSV64804979; called by muse, mutect2
- GABRA5 | c.456G>T p.L152= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- GIGYF1 | c.831G>T p.R277= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- GPR26 | c.858G>A p.K286= | Silent (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- GRIA3 | c.1587C>T p.G529= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV52048767; called by muse, mutect2
- GRIN2A | c.618G>T p.L206= | Silent (SNP) | VAF 10/288 reads (3%) | catalogued as COSV58027892; called by muse, mutect2
- HERC2 | c.6048G>C p.V2016= | Silent (SNP) | VAF 9/209 reads (4%) | called by muse, mutect2
- HLF | c.48G>T p.P16= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV56828865; called by muse, mutect2
- HMCN2 | c.13695G>A p.Q4565= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- HNRNPLL | c.1233A>T p.S411= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- IFNA6 | c.381G>A p.V127= | Silent (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- IFT122 | c.3453A>T p.T1151= (on ENST00000348417 / NM_052989.3; = p.T1092= on NM_018262.4) | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- JCAD | c.3822G>A p.L1274= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- KCND1 | c.972T>C p.S324= | Silent (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- L3MBTL4 | c.1806G>T p.L602= | Silent (SNP) | VAF 18/244 reads (7%) | catalogued as rs964027486; called by muse, mutect2
- LCN10 | c.468G>A p.L156= (on ENST00000474369 / NM_001368089.1; = p.L169= on NM_001001712.3) | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as rs1372787759; called by muse, mutect2
- LMBR1 | c.1434A>C p.T478= | Silent (SNP) | VAF 11/230 reads (5%) | called by muse, mutect2
- LRFN5 | c.1419C>A p.V473= | Silent (SNP) | VAF 17/400 reads (4%) | called by muse, mutect2
- LRIG1 | c.513A>T p.A171= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- LRRC14B | c.1341C>T p.N447= | Silent (SNP) | VAF 18/285 reads (6%) | called by muse, mutect2
- MACF1 | c.2046G>T p.L682= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- MAGEA3 | c.342C>A p.A114= | Silent (SNP) | VAF 35/202 reads (17%) | called by muse, mutect2, varscan2
- MAGEL2 | c.3279G>T p.L1093= | Silent (SNP) | VAF 11/184 reads (6%) | catalogued as COSV100046215; called by muse, mutect2
- MIB1 | c.567A>T p.P189= | Silent (SNP) | VAF 11/299 reads (4%) | called by muse, mutect2
- NCOA1 | c.3828G>T p.G1276= | Silent (SNP) | VAF 11/205 reads (5%) | catalogued as rs901454201; called by muse, mutect2
- NKX1-1 | c.477C>A p.P159= | Silent (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- NOS1 | c.4080T>A p.A1360= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- NXPE3 | c.1332A>G p.V444= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- OBSCN | c.7149G>T p.R2383= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- OR4C11 | c.543C>A p.P181= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100155086; called by muse, mutect2
- OR8K3 | c.390G>T p.L130= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- PCDH19 | c.891G>T p.L297= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV99720678; called by muse, mutect2, varscan2
- PCDHB9 | c.1044C>T p.I348= | Silent (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- PCDHGA9 | c.540G>T p.L180= | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- PNCK | c.633C>T p.P211= (on ENST00000340888 / NM_001366975.1; = p.P294= on NM_001039582.3) | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs782622364, COSV61745231; called by muse, mutect2, varscan2
- PRKDC | c.9660G>T p.V3220= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- PTGS1 | c.87C>A p.P29= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- RAB3GAP2 | c.2652G>A p.E884= | Silent (SNP) | VAF 16/269 reads (6%) | called by muse, mutect2
- RASGRF2 | c.2181C>T p.S727= | Silent (SNP) | VAF 21/279 reads (8%) | catalogued as COSV54135245; called by muse, mutect2
- RFPL2 | c.255C>A p.S85= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- RYR1 | c.11595C>T p.I3865= | Silent (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- SLC34A1 | c.1497C>T p.R499= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as rs928799060; called by muse, mutect2
- SLIT3 | c.4110C>T p.D1370= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- SMOC1 | c.741C>T p.V247= | Silent (SNP) | VAF 7/177 reads (4%) | called by muse, mutect2
- SOHLH1 | c.234C>T p.A78= | Silent (SNP) | VAF 14/205 reads (7%) | called by muse, mutect2
- SPHKAP | c.258G>A p.V86= | Silent (SNP) | VAF 10/251 reads (4%) | catalogued as COSV100763956; called by muse, mutect2
- SVEP1 | c.8682G>T p.P2894= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs754856358; called by muse, mutect2
- TIE1 | c.2511G>A p.E837= | Silent (SNP) | VAF 9/287 reads (3%) | catalogued as rs907565967; called by muse, mutect2
- TMEM229A | c.792A>T p.V264= | Silent (SNP) | VAF 7/181 reads (4%) | called by muse, mutect2
- TTN | c.28923C>T p.L9641= (on ENST00000591111; = p.L8714= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as rs972874110, COSV59986559, COSV60202278; called by muse, mutect2
- TTN | c.6849A>T p.S2283= (on ENST00000591111; = p.S2237= on NM_003319.4) | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- TWIST1 | c.96C>A p.G32= | Silent (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- UGT2B10 | c.1426C>A p.R476= | Silent (SNP) | VAF 33/520 reads (6%) | catalogued as COSV99608695; called by muse, mutect2
- USP18 | c.48G>T p.L16= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2, varscan2
- USP26 | c.189C>A p.S63= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- VSIG10L | c.1053C>A p.A351= | Silent (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- ZFHX2 | c.201C>T p.L67= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1403137607; called by muse, mutect2
- ZKSCAN5 | c.1317C>T p.F439= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs372702618; called by muse, mutect2
- ZNF79 | c.1242G>A p.E414= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as rs879209574; called by muse, mutect2
- ABCB7 | chrX:75156707 G>T | 5'Flank (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- AC016582.1 | chr19:37824446 G>A | 3'Flank (SNP) | VAF 8/201 reads (4%) | called by muse, mutect2
- AC074085.2 | n.176G>T | RNA (SNP) | VAF 13/174 reads (7%) | called by muse, mutect2
- AC136628.2 | n.629G>C | RNA (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- AC136759.1 | n.621C>T | RNA (SNP) | VAF 13/362 reads (4%) | called by muse, mutect2
- AGAP3 | c.1020+404G>T | Intron (SNP) | VAF 10/131 reads (8%) | catalogued as COSV58993805; called by muse, mutect2
- AL353804.7 | chrX:73847775 G>C | 5'Flank (SNP) | VAF 11/163 reads (7%) | catalogued as rs1284671391; called by muse, mutect2
- ALMS1P1 | chr2:73700852 C>G | 3'Flank (SNP) | VAF 13/285 reads (5%) | called by muse, mutect2
- AREG | c.311-39G>T | Intron (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- ARHGEF25 | chr12:57620347 G>T | 3'Flank (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- ASXL1 | c.57+474G>T | Intron (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- ATP13A2 | c.1542+84C>T | Intron (SNP) | VAF 10/96 reads (10%) | catalogued as rs1388597727; called by muse, mutect2
- CACNB2 | c.213+110326G>T | Intron (SNP) | VAF 15/438 reads (3%) | called by muse, mutect2
- CASR | c.1378-6258G>T | Intron (SNP) | VAF 21/368 reads (6%) | catalogued as COSV56140647; called by muse, mutect2
- CATSPER3 | c.*11G>C | 3'UTR (SNP) | VAF 15/293 reads (5%) | called by muse, mutect2
- CCDC150 | c.-43G>A | 5'UTR (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- CDON | c.*4690G>C | 3'UTR (SNP) | VAF 8/241 reads (3%) | called by muse, mutect2
- CFAP74 | c.2176+413C>A | Intron (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- COL4A2 | c.648+211C>A | Intron (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- COMMD9 | chr11:36271666 C>A | 3'Flank (SNP) | VAF 9/244 reads (4%) | called by muse, mutect2
- CRISPLD2 | c.240+36G>T | Intron (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- CRTAM | c.-12G>A | 5'UTR (SNP) | VAF 11/195 reads (6%) | called by muse, mutect2
- FCRL1 | c.1186+112G>A | Intron (SNP) | VAF 16/286 reads (6%) | catalogued as rs927669595; called by muse, mutect2
- FMR1 | c.*963G>T | 3'UTR (SNP) | VAF 12/178 reads (7%) | catalogued as rs1557183107; called by muse, mutect2
- FOXP2 | c.*2116G>T | 3'UTR (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- HOOK2 | c.1606-24C>G | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- INTS3 | c.2821+97C>A | Intron (SNP) | VAF 7/100 reads (7%) | called by muse, mutect2
- KDR | c.1987+25G>T | Intron (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- LINC01387 | n.380G>A | RNA (SNP) | VAF 10/259 reads (4%) | catalogued as rs1383999345; called by muse, mutect2
- LINC02756 | n.311+7261G>A | Intron (SNP) | VAF 10/208 reads (5%) | catalogued as rs1340134134; called by muse, mutect2
- MGAT4EP | n.1343T>C | RNA (SNP) | VAF 15/326 reads (5%) | called by muse, mutect2
- MMGT1 | c.-5G>T | 5'UTR (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- MUC13 | c.800+17C>A | Intron (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
- NDUFV3 | c.-31G>T | 5'UTR (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- NECTIN1 | c.79+14657C>G | Intron (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- NRG1 | c.502+31216T>G | Intron (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- OR10D1P | n.192G>C | RNA (SNP) | VAF 20/464 reads (4%) | called by muse, mutect2
- OSBPL2 | chr20:62232984 C>A | 5'Flank (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- PAGE5 | c.*34G>C | 3'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as COSV56943177; called by muse, mutect2
- PEX5L | c.199-362C>A | Intron (SNP) | VAF 18/205 reads (9%) | called by muse, mutect2
- POLR3D | chr8:22245041 A>G | 5'Flank (SNP) | VAF 7/55 reads (13%) | catalogued as rs757641830; called by muse, mutect2, varscan2
- PRB4 | c.-12G>T | 5'UTR (SNP) | VAF 18/401 reads (4%) | catalogued as COSV99686682; called by muse, mutect2
- PRR14L | chr22:31676955 A>G | 3'Flank (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- PRSS58 | c.-26A>T | 5'UTR (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- PSG1 | c.*66C>G | 3'UTR (SNP) | VAF 12/378 reads (3%) | catalogued as rs1368103240; called by muse, mutect2
- RN7SL484P | chr15:99790207 G>T | 5'Flank (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- RN7SL484P | chr15:99792558 C>T | 3'Flank (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- SGCA | c.983+1141C>G | Intron (SNP) | VAF 13/205 reads (6%) | called by muse, mutect2
- SLC19A3 | c.150+1228C>A | Intron (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- SNORD115-18 | n.17C>T | RNA (SNP) | VAF 12/268 reads (4%) | catalogued as rs1269443770; called by muse, mutect2
- SOX8 | chr16:976866 G>T | 5'Flank (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- SSPOP | n.13256C>A | RNA (SNP) | VAF 4/78 reads (5%) | catalogued as COSV65134193; called by muse, mutect2
- TAF1D | c.*20+10A>T | Intron (SNP) | VAF 9/229 reads (4%) | called by muse, mutect2
- TEKT4 | c.499-660G>T | Intron (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- TMEM135 | c.*2171A>T | 3'UTR (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- TPO | c.2748+87C>A | Intron (SNP) | VAF 12/140 reads (9%) | called by muse, mutect2
- TSHZ2 | c.*1917G>T | 3'UTR (SNP) | VAF 19/533 reads (4%) | catalogued as rs1434932526; called by muse, mutect2
- TTYH1 | chr19:54415284 G>T | 5'Flank (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- VIM | c.-21C>A | 5'UTR (SNP) | VAF 5/90 reads (6%) | catalogued as rs1478357437; called by muse, mutect2
- XAB2 | c.-12G>C | 5'UTR (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
